RC case RC-B5D0 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4dfbecbd-d649-4043-a9c3-e97f768ad884

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1937; Vital status: Dead; Days to death: 418 days (1.1 years); Year of death: 2018; Cause of death: Cancer Related.

Diagnoses (6)
1. Peripheral T-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 80.2 years (29,284 days); Year of diagnosis: 2017; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bortezomib + Duvelisib; Initial disease status: Progressive Disease; Days to treatment start: 19 days; Days to treatment end: 193 days; Number of cycles: 4; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide; Initial disease status: Initial Diagnosis; Days to treatment start: 19 days; Days to treatment end: 40 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Romidepsin; Initial disease status: Progressive Disease; Days to treatment start: 210 days; Days to treatment end: 224 days; Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: MDM2/MDMX Inhibitor ALRN-6924; Initial disease status: Progressive Disease; Days to treatment start: 256 days; Days to treatment end: 281 days; Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Progressive Disease; Days to treatment start: 294 days; Days to treatment end: 379 days (1.0 years); Treatment outcome: Partial Response; Reason treatment ended: Other; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Stopped Due to Toxicity; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC). Age at diagnosis: 69.5 years (25,389 days); Year of diagnosis: 2007; Days to diagnosis: -3,895 days (-10.7 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -3,895 days (-10.7 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.
3. Progression (histology not recorded by GDC). Age at diagnosis: 80.3 years (29,330 days); Days to diagnosis: 46 days.
4. Progression (histology not recorded by GDC). Age at diagnosis: 80.7 years (29,480 days); Days to diagnosis: 196 days.
5. Progression (histology not recorded by GDC). Age at diagnosis: 80.8 years (29,522 days); Days to diagnosis: 238 days.
6. Progression (histology not recorded by GDC). Age at diagnosis: 81.0 years (29,575 days); Days to diagnosis: 291 days.

Follow-up (7 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Day 46 (progression): Progression or recurrence: Yes; Days to progression: 46 days.
- Day 196 (progression): Progression or recurrence: Yes; Days to progression: 196 days.
- Day 238 (progression): Progression or recurrence: Yes; Days to progression: 238 days.
- Day 291 (progression): Progression or recurrence: Yes; Days to progression: 291 days.
- Days to follow up: 312 days; Disease response: Partial Response.
- Day 418 (end of treatment course 1): Disease response: With Tumor.

Molecular and laboratory tests
- Epstein-Barr Virus: Negative [Test analyte type: DNA].
- Lactate Dehydrogenase 228 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 97.1 kg; Height: 173 cm; BMI: 32.4.
- Timepoint category: Prior to Diagnosis; Comorbidities: Ulcerative Colitis / Arthritis / Hypertension / Neuropathy / Neuroma / Erectile Dysfunction.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 1977.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Leukemia.

Biospecimens (3 samples)
- Sample RC-B5D0-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5D0-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample RC-B5D0-TBR1-A: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
